Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8384, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8384-01A (Primary Tumor).

[page 1 of 2]
Patient ID:

Surgical Date:

Gross Description: Dissected stomach, 11 cm along the lesser curvature, 19 cm along the greater curvature, with greater and lesser omentum;

in the antral part along the anterior wall with the transition on the lesser curvature there is an exophytic tumour of 6 x 5.5 x 1 cm, dense-elastic, white-pinkish, invades all wall layers;

greater and lesser curvature lymph nodes are of 0.2 -0.7 cm (eighteen)

Microscopic Description: Poorly differentiated adenocarcinoma of the stomach with all wall layers and in lesser omentum tissues invasion;

eighteen lymph nodes were examined, six demonstrated metastases;

vessels and surgical margins are free of tumor elements.

Diagnosis Details: Tumor Features: Exophytic (polypoid), Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Total gastrectomy

Tumor site: Antrum

Tumor size: 5.5 x 1 x 6 cm

Tumor features: Exophytic (polypoid)

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Other - Lesser omentum

Lymph nodes: 6/18 positive for metastasis (Greater and lesser curvature 6/18)

Lymphatic invasion: Not specified

Venous invasion: Absent

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: Antrum C16.3

for
11/5/13

[page 2 of 2]
Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file d433d820-22c7-4fda-8c33-89fbefaa75e4 (TCGA-BR-8384.6030394B-10EF-4707-A0BF-25B82AC7EC84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).